Gene-level copy-number profile of tumor specimen C3L-05865-54 from CPTAC case C3L-05865, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 18.8 years (6,869 days).
Specimen C3L-05865-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21a82003-2375-4798-97d8-3d7cf15e891b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05865-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/20777b9f-12a4-45c8-a2ea-0f708eb222b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 197; copy number 2: 48,877; copy number 3: 9,305.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,652,374–185,800,151, 1 gene (within-gene range 0–2): FSIP2-AS1.
- chr2:185,738,804–185,833,290, 1 gene (within-gene range 0–2): FSIP2.
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr9:65,189,995–65,323,015, 6 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr17:22,671,433–22,706,703, 3 genes: AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
